Somatic mutation profile of tumor specimen C3N-01082-03 (aliquot CPT0211680006) from CPTAC case C3N-01082, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G2.
Specimen C3N-01082-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 288c0330-1fc2-4af6-8c5e-a71328b4676e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01082-71 (Blood Derived Normal), aliquot CPT0211780002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0e7083f-7f39-4689-827c-80484889dd4c

The open-access MAF lists 92 somatic variants for this specimen: 58 protein-altering or splice-affecting, 21 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 21, Frame Shift Del 9, Intron 8, Nonsense Mutation 6, In Frame Del 2, Splice Site 1, RNA 1, Splice Region 1, 3'UTR 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSF2 | c.104G>C p.R35T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.007); catalogued as rs1000880439; called by muse, mutect2, varscan2
- ARHGAP18 | c.1258C>T p.L420F | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs771726436, COSV63763651; called by muse, mutect2, varscan2
- ARL4D | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 68/474 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs1350755959; called by muse, mutect2, varscan2
- BBS12 | c.1005C>G p.I335M | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV58563147; called by muse, mutect2
- BMS1 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs914443446; called by muse, mutect2, varscan2
- DISP1 | c.2652G>T p.E884D | Missense Mutation (SNP) | VAF 60/470 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs138904556, COSV52660193; called by muse, mutect2, varscan2
- DYNC1LI2 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99263251; called by mutect2, varscan2
- H3C13 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 63/573 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV100516177; called by muse, mutect2, varscan2
- INTS7 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 25/275 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1239475792, COSV100877490; called by muse, mutect2
- ITLN2 | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV63538292; called by muse, mutect2, varscan2
- NDUFS1 | c.1776G>C p.K592N | Missense Mutation (SNP) | VAF 29/311 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51913329, COSV99261268; called by muse, mutect2
- PANK2 | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs780151182; called by muse, mutect2, varscan2
- PBRM1 | c.3388-2A>G p.X1130_splice (on ENST00000296302 / NM_001366071.2; = p.X1105_splice on NM_018313.5) | Splice Site (SNP) | VAF 33/160 reads (21%) | catalogued as COSV56284329; called by muse, mutect2, varscan2
- PTCH1 | c.2945G>A p.R982Q | Missense Mutation (SNP) | VAF 80/475 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.183); catalogued as rs145924695, CM135270; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- PTPRZ1 | c.1738G>C p.D580H | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.023); catalogued as COSV66447894; called by muse, mutect2, varscan2
- RASEF | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 12/90 reads (13%) | catalogued as COSV100906811, COSV100907061; called by muse, mutect2, varscan2
- SMC5 | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs762963288; called by muse, mutect2, varscan2
- SPAG17 | c.3133C>T p.Q1045* | Nonsense Mutation (SNP) | VAF 22/253 reads (9%) | catalogued as COSV60454001; called by muse, mutect2
- SUN5 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1419991350; called by muse, mutect2, varscan2
- TACC3 | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs780833702; called by muse, mutect2, varscan2
- TRIM49B | c.374G>A p.R125K | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.027); catalogued as rs535054591; called by muse, mutect2
- TSC1 | c.1825G>T p.E609* | Nonsense Mutation (SNP) | VAF 65/346 reads (19%) | catalogued as rs118203587, CM016250, COSV53765370; ClinVar: not provided; called by muse, mutect2, varscan2
- TUBB8 | c.167-5C>G | Splice Region (SNP) | VAF 37/407 reads (9%) | catalogued as COSV59115190; called by muse, mutect2
- ZSCAN10 | c.586G>A p.V196M (on ENST00000252463; = p.V251M on NM_032805.3) | Missense Mutation (SNP) | VAF 37/343 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.707); catalogued as rs768700381; called by muse, mutect2, varscan2
- ACACB | c.711C>A p.D237E | Missense Mutation (SNP) | VAF 77/430 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- B4GALNT4 | c.2074G>C p.D692H | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- BAP1 | c.163_180del p.E55_R60del | In Frame Del (DEL) | VAF 40/270 reads (15%) | called by mutect2, pindel
- C19orf12 | c.51_53del p.E17del (on ENST00000392278 / NM_001031726.3; = p.E6del on NM_031448.6) | In Frame Del (DEL) | VAF 71/598 reads (12%) | called by pindel, varscan2
- CCNG1 | c.767A>T p.K256M | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CD58 | c.532del p.E178Kfs*25 | Frame Shift Del (DEL) | VAF 14/135 reads (10%) | called by mutect2, varscan2
- CTR9 | c.2643_2677del p.Y881* | Nonsense Mutation (DEL) | VAF 34/350 reads (10%) | called by mutect2, pindel
- DAGLA | c.858G>T p.M286I | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- DLX6 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 43/333 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DROSHA | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2
- FBXL17 | c.155_171del p.D52Afs*237 | Frame Shift Del (DEL) | VAF 14/124 reads (11%) | called by mutect2, pindel
- FLRT3 | c.1357_1366del p.T453Lfs*2 | Frame Shift Del (DEL) | VAF 19/148 reads (13%) | called by mutect2, pindel
- FSCN2 | c.1402T>G p.Y468D | Missense Mutation (SNP) | VAF 101/471 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GBP6 | c.518T>A p.F173Y | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- GIGYF2 | c.2969G>A p.G990E | Missense Mutation (SNP) | VAF 40/332 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IGBP1P2 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KIAA1328 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2
- LRP2 | c.5726del p.S1909Lfs*2 | Frame Shift Del (DEL) | VAF 42/352 reads (12%) | called by mutect2, pindel, varscan2
- LRP4 | c.194G>C p.G65A | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- MFSD12 | c.1024_1028del p.M342Lfs*70 | Frame Shift Del (DEL) | VAF 14/146 reads (10%) | called by mutect2, pindel
- NT5DC1 | c.375del p.Y127Tfs*20 | Frame Shift Del (DEL) | VAF 15/147 reads (10%) | called by mutect2, pindel, varscan2
- NTRK2 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- PIWIL1 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 87/367 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- PPP2R5C | c.477T>G p.I159M | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- RBMXL3 | c.2837G>T p.G946V | Missense Mutation (SNP) | VAF 13/262 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); called by muse, mutect2
- SLX4 | c.1696G>T p.E566* | Nonsense Mutation (SNP) | VAF 27/217 reads (12%) | called by muse, varscan2
- STYK1 | c.1040G>A p.R347K | Missense Mutation (SNP) | VAF 19/280 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.058); called by muse, mutect2
- TACR2 | c.410A>G p.H137R | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2
- TCEAL4 | c.259G>T p.G87* | Nonsense Mutation (SNP) | VAF 33/224 reads (15%) | called by muse, mutect2, varscan2
- TTC13 | c.999del p.F333Lfs*27 | Frame Shift Del (DEL) | VAF 37/189 reads (20%) | called by mutect2, pindel, varscan2
- TYMP | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 57/473 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VHL | c.176_203del p.P59Rfs*91 | Frame Shift Del (DEL) | VAF 74/564 reads (13%) | called by mutect2, pindel
- ZNF573 | c.1481del p.G494Vfs*30 (on ENST00000536220 / NM_001172692.1; = p.G436Vfs*30 on NM_152360.3) | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | called by mutect2, pindel, varscan2
- ZNF846 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- CDC14B | c.1041C>T p.C347= | Silent (SNP) | VAF 23/184 reads (13%) | catalogued as rs1344054461; called by muse, mutect2, varscan2
- CDK12 | c.1326G>A p.L442= | Silent (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2, varscan2
- CYP2R1 | c.615C>T p.T205= | Silent (SNP) | VAF 16/298 reads (5%) | catalogued as rs554176344; called by muse, mutect2
- DLG4 | c.867T>C p.T289= (on ENST00000399506 / NM_001321075.3; = p.T332= on NM_001365.4) | Silent (SNP) | VAF 14/251 reads (6%) | called by muse, mutect2
- DSE | c.750G>T p.V250= | Silent (SNP) | VAF 42/416 reads (10%) | catalogued as COSV59061463; called by muse, mutect2
- FAM50B | c.975C>A p.R325= | Silent (SNP) | VAF 22/190 reads (12%) | called by mutect2, varscan2
- FKBP15 | c.2817C>T p.S939= | Silent (SNP) | VAF 34/154 reads (22%) | called by muse, mutect2
- HOMEZ | c.279G>A p.G93= | Silent (SNP) | VAF 18/190 reads (9%) | catalogued as rs756332834; called by muse, mutect2
- HOXB4 | c.618C>T p.I206= | Silent (SNP) | VAF 124/580 reads (21%) | catalogued as rs774903494, COSV100203837; called by muse, mutect2, varscan2
- KRT74 | c.1164C>T p.D388= | Silent (SNP) | VAF 72/717 reads (10%) | catalogued as rs185121430; called by muse, mutect2
- MAP3K15 | c.285C>T p.G95= | Silent (SNP) | VAF 56/444 reads (13%) | called by muse, mutect2, varscan2
- PLXND1 | c.1683G>A p.A561= | Silent (SNP) | VAF 40/368 reads (11%) | catalogued as rs756224333; called by muse, mutect2, varscan2
- PRAG1 | c.258G>A p.V86= | Silent (SNP) | VAF 30/212 reads (14%) | called by muse, mutect2, varscan2
- SETDB1 | c.2034T>C p.Y678= | Silent (SNP) | VAF 34/360 reads (9%) | called by muse, mutect2
- SLC14A2 | c.786G>T p.L262= | Silent (SNP) | VAF 30/250 reads (12%) | catalogued as COSV99676377; called by muse, mutect2, varscan2
- SLC26A4 | c.576G>A p.L192= | Silent (SNP) | VAF 40/317 reads (13%) | catalogued as rs750458526; called by muse, mutect2, varscan2
- SMARCA5 | c.1722A>C p.V574= | Silent (SNP) | VAF 21/160 reads (13%) | called by muse, mutect2, varscan2
- TBC1D16 | c.1281T>C p.D427= | Silent (SNP) | VAF 60/262 reads (23%) | called by muse, mutect2, varscan2
- TYMP | c.543C>T p.G181= | Silent (SNP) | VAF 57/471 reads (12%) | called by muse, mutect2, varscan2
- ZNF469 | c.2289C>T p.G763= | Silent (SNP) | VAF 25/181 reads (14%) | called by muse, mutect2, varscan2
- ZNF618 | c.471G>A p.K157= (on ENST00000374126 / NM_001318042.2; = p.K125= on NM_133374.2) | Silent (SNP) | VAF 45/303 reads (15%) | called by muse, mutect2, varscan2
- AP001496.3 | chr18:5238214 C>T | 3'Flank (SNP) | VAF 28/219 reads (13%) | called by muse, mutect2, varscan2
- CCDC88B | c.2862+42G>T | Intron (SNP) | VAF 17/150 reads (11%) | called by muse, mutect2
- CFAP99 | c.370-78G>A | Intron (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- CHID1 | c.-44+113G>C | Intron (SNP) | VAF 27/149 reads (18%) | called by muse, mutect2, varscan2
- ENOSF1 | c.1021-821G>A | Intron (SNP) | VAF 24/246 reads (10%) | called by muse, mutect2
- INTS4 | c.1922+721C>T | Intron (SNP) | VAF 9/255 reads (4%) | called by muse, mutect2
- KLHL2 | c.1754-666T>G | Intron (SNP) | VAF 18/140 reads (13%) | called by muse, mutect2, varscan2
- KRT13 | c.-32T>G | 5'UTR (SNP) | VAF 46/367 reads (13%) | called by muse, mutect2, varscan2
- PRELID1 | c.512-12C>A | Intron (SNP) | VAF 30/316 reads (9%) | catalogued as COSV57463601; called by muse, mutect2
- SEC23IP | c.*9C>T | 3'UTR (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2, varscan2
- SSPOP | n.13788T>C | RNA (SNP) | VAF 20/158 reads (13%) | catalogued as rs939969830; called by muse, mutect2, varscan2
- TPGS2 | chr18:36829208 C>A | 5'Flank (SNP) | VAF 26/187 reads (14%) | called by muse, mutect2, varscan2
- VWA3A | c.351-24C>T | Intron (SNP) | VAF 48/284 reads (17%) | called by muse, mutect2, varscan2
